Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GK, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GK-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate/poor differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: diameter 5 cm

Lymph node status: 5 lymph nodes, of which 3 contains tumor

Any comments or amendments: radical resection

ICD-O-3
Adenocarcinoma, NOS
8/40/3
Site: Esophagus, distal
thick C15.5
J 1/29/14

Source: NCI Genomic Data Commons file 63b7bc8b-521a-4818-932f-f0bead3e0b7c (TCGA-2H-A9GK.5D0508E6-8DA2-4B51-B00A-1B54AA6CC20D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).